Gene-level copy-number profile of specimen HCM-BROD-0677-C43-85M from HCMI case HCM-BROD-0677-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.1 years (20,120 days).
Specimen HCM-BROD-0677-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7fb35db3-29e0-4eba-8827-baa9e5d621a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0677-C43-12A (saliva); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b9c6130b-d770-45aa-b6a2-a42daeb8397d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 52; copy number 2: 7,026; copy number 3: 25,989; copy number 4: 17,645; copy number 5: 4,901; copy number 6: 2,569; copy number 7: 100; copy number 8: 30; copy number 9: 28; copy number 10: 9; copy number 11: 30; copy number 65: 2; copy number 68: 8; copy number 69: 1; copy number 71: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 212 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,367,466–55,484,972, 5 genes, copy number 7: GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA.
- chr1:62,236,165–62,905,482, 12 genes, copy number 8: KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2.
- chr4:34,714,270–34,966,344, 2 genes, copy number 8–10: AC093913.1, AC020589.1.
- chr4:36,496,128–36,641,939, 1 gene, copy number 9 (within-gene range 6–9): LINC02505.
- chr4:37,001,772–38,782,990, 28 genes, copy number 7–10: LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10.
- chr4:39,287,456–40,355,217, 37 genes, copy number 9–11: RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, RHOH, AC095057.2, LINC02265, CHRNA9.
- chr4:40,423,267–40,630,875, 4 genes, copy number 7: RBM47, AC098869.2, AC098869.1, MIR4802.
- chr4:40,810,027–41,216,714, 1 gene, copy number 8 (within-gene range 6–8): APBB2.
- chr4:40,990,154–41,960,803, 18 genes, copy number 8–9: RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, TMEM33.
- chr4:43,972,921–44,025,516, 2 genes, copy number 7: AC114757.1, LINC02475.
- chr8:127,072,694–127,227,541, 1 gene, copy number 68 (within-gene range 4–68): CASC19.
- chr8:127,289,817–127,742,951, 7 genes, copy number 68: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr8:128,634,199–129,683,770, 1 gene, copy number 65 (within-gene range 4–65): CCDC26.
- chr8:129,484,057–129,484,142, 1 gene, copy number 65: MIR3686.
- chr8:132,775,358–133,134,903, 4 genes, copy number 71 (within-gene range 3–71): PHF20L1, AF230666.2, AF230666.1, TG.
- chr8:138,588,235–138,914,041, 1 gene, copy number 69: COL22A1.
- chr10:12,129,637–12,835,545, 13 genes, copy number 8–9: SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q.
- chr10:14,518,557–14,954,432, 10 genes, copy number 7: FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C.
- chr10:14,999,050–15,171,278, 11 genes, copy number 7: OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1.
- chr10:15,778,170–16,207,927, 3 genes, copy number 7–9: MINDY3, FTLP19, RNU6-1075P.
- chr10:16,436,943–17,202,054, 10 genes, copy number 7–8: PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, CUBN, AC067747.1, TRDMT1.
- chr10:17,228,241–17,911,164, 15 genes, copy number 7–8 (within-gene range 6–8): VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1.
- chr10:36,432,882–36,524,234, 5 genes, copy number 7–9: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1.
- chr20:62,307,955–62,367,312, 1 gene, copy number 7 (within-gene range 6–7): LAMA5.
- chr20:62,352,995–62,478,594, 9 genes, copy number 7: LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2.
- chr22:15,489,990–15,492,564, 1 gene, copy number 10: YME1L1P1.
- chr22:15,635,180–15,829,984, 9 genes, copy number 7 (within-gene range 3–7): MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1.

Autosomal genes at a single copy (total copy number 1): 52. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
